Gene-level copy-number profile of tumor specimen HCM-CSHL-0853-C56-07A from HCMI case HCM-CSHL-0853-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: High Grade.
Specimen HCM-CSHL-0853-C56-07A: Sample type: Additional Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 05721ed5-83fc-4079-8113-800e35bec000.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0853-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/3b2bacde-39cb-4c1c-a1ae-403b3f3ca10d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 79; copy number 1: 20,532; copy number 2: 29,855; copy number 3: 5,298; copy number 4: 2,482; copy number 5: 148.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr6:114,349,483–114,350,648, 1 gene (within-gene range 0–1): DNAJA1P4.
- chr8:8,086,022–8,116,949, 4 genes: AC105233.2, MIR548I3, RPS3AP31, SNRPCP17.
- chr9:12,134–89,850, 7 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1.
- chr9:21,135,598–22,214,672, 51 genes: AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr21:44,107,373–44,210,114, 5 genes (within-gene range 0–1): PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 148 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:75,921,114–76,072,678, 1 gene, copy number 5 (within-gene range 3–5): IMPG1.
- chr6:76,092,834–76,092,940, 1 gene, copy number 5: RNU6-248P.
- chr8:102,503,753–102,622,331, 5 genes, copy number 5: RPS12P15, AP002852.1, RNU6-1224P, ODF1, POU5F1P2.
- chr8:107,857,589–110,105,964, 28 genes, copy number 5: AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, AC023245.1, KCNV1, AC027451.1, RPSAP48.
- chr9:60,914,407–61,642,494, 15 genes, copy number 5: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr11:73,400,487–73,598,189, 1 gene, copy number 5 (within-gene range 4–5): FAM168A.
- chr11:73,452,020–73,931,114, 14 genes, copy number 5: AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4.
- chr11:100,641,975–102,727,050, 36 genes, copy number 5: RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8.
- chr11:111,089,870–112,086,798, 47 genes, copy number 5 (within-gene range 4–5): AP003973.2, LINC02550, AP003973.3, RPS17P15, AP003973.1, C11orf53, COLCA1, COLCA2, MIR4491, POU2AF1, RNU2-60P, AP002008.3, AP002008.2, BTG4, AP002008.4, MIR34B, MIR34C, AP002008.1, HOATZ, LAYN, SIK2, AP000925.1, RN7SKP273, PPP2R1B, AP001781.1, ALG9, AP001781.2, ALG9-IT1, GNG5P3, FDXACB1, C11orf1, RPL37AP8, CRYAB, HSPB2, HSPB2-C11orf52, C11orf52, DIXDC1, RNA5SP351, AP000907.1, AP000907.2, DLAT, PPIHP1, RNU6-893P, AP000907.3, PIH1D2, NKAPD1, TIMM8B.

Autosomal genes at a single copy (total copy number 1): 19,760. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
